Somatic mutation profile of tumor specimen TCGA-EO-A22S-01A (aliquot TCGA-EO-A22S-01A-11D-A18P-09) from TCGA case TCGA-EO-A22S, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 58.4 years (21,328 days).
Specimen TCGA-EO-A22S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ae4c6ca-e73e-41c9-b9e3-c8192fdfe928.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A22S-11A (Solid Tissue Normal), aliquot TCGA-EO-A22S-11A-11D-A18P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/287cd630-039b-47f8-9af9-a49f33b547e6

The open-access MAF lists 787 somatic variants for this specimen: 600 protein-altering or splice-affecting, 167 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 351, Frame Shift Del 174, Silent 167, Frame Shift Ins 38, Nonsense Mutation 18, In Frame Del 8, Splice Site 6, RNA 6, Intron 6, Splice Region 3, 3'UTR 2, 5'UTR 2.

Variants (750 of 787; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 61/138 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- EIF1AX | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 55/121 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV63309291, COSV63309392, COSV63309466; called by muse, mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KANSL1 | c.779del p.G260Vfs*19 | Frame Shift Del (DEL) | VAF 11/81 reads (14%) | catalogued as rs748018297; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KCNQ1 | c.1893del p.R632Efs*34 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | catalogued as rs397508104; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 22/51 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAT1A | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376993881, CM106329; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 36/60 reads (60%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 24/61 reads (39%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AADAC | c.318del p.L107Cfs*16 | Frame Shift Del (DEL) | VAF 38/97 reads (39%) | catalogued as COSV99233520; called by mutect2, pindel, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs770970036; called by mutect2, varscan2
- ABCA7 | c.1279C>T p.Q427* | Nonsense Mutation (SNP) | VAF 43/79 reads (54%) | catalogued as COSV99566546; called by muse, mutect2, varscan2
- ABCC8 | c.3938G>A p.R1313H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372153432, CM077499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABLIM2 | c.354del p.D120Tfs*3 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs749606695; called by mutect2, pindel, varscan2
- ACAP1 | c.620A>G p.H207R | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV99341939; called by muse, mutect2, varscan2
- ACE | c.3508G>A p.A1170T | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.704); catalogued as rs747412511, COSV52004839, COSV99326513; called by muse, mutect2, varscan2
- ACSF3 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV100441534; called by muse, mutect2, varscan2
- ACTC1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV51758756; called by muse, mutect2, varscan2
- ACTL7B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs139165156; called by muse, mutect2, varscan2
- ACVR2A | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.391); catalogued as COSV54022613; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 39/81 reads (48%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTSL4 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs150503018, COSV55001451, COSV99647395; called by muse, mutect2, varscan2
- ADGRV1 | c.17341C>T p.Q5781* | Nonsense Mutation (SNP) | VAF 29/81 reads (36%) | catalogued as COSV101316405, COSV101316665; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 42/92 reads (46%) | catalogued as rs761350619; called by mutect2, varscan2
- AGBL1 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs370819074, COSV66847496; called by muse, mutect2, varscan2
- AGO2 | c.1806dup p.A603Rfs*71 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | catalogued as rs748399150; called by mutect2, varscan2
- AHNAK | c.15725G>A p.G5242D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99949301; called by muse, mutect2, varscan2
- AHRR | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs747743842, COSV100327910; called by muse, mutect2, varscan2
- AIP | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.947); catalogued as COSV99653811; called by muse, mutect2, varscan2
- AL133500.1 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious, low confidence (0.01); catalogued as COSV99860455; called by muse, mutect2, varscan2
- ALKBH4 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99479529; called by muse, mutect2, varscan2
- ANGPTL2 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs778400951, COSV99402456; called by muse, mutect2, varscan2
- ANKRD26 | c.4970A>G p.E1657G | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV101063359; called by muse, mutect2, varscan2
- ANKS3 | c.995G>A p.S332N | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1178570081, COSV100423254; called by muse, mutect2
- ANO8 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212896037, COSV50175176; called by muse, mutect2, varscan2
- AP5M1 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as rs1189483422, COSV99841329; called by muse, mutect2, varscan2
- APBB1 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV100194277; called by muse, mutect2, varscan2
- APOA5 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as rs781109287, COSV99911196, COSV99911379; called by muse, mutect2, varscan2
- APOB | c.9923A>G p.H3308R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99267544; called by muse, mutect2, varscan2
- APOB | c.3817A>G p.I1273V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1350293648, COSV99267549; called by muse, mutect2, varscan2
- APPL1 | c.460dup p.R154Kfs*4 | Frame Shift Ins (INS) | VAF 34/95 reads (36%) | catalogued as rs749401724; called by mutect2, varscan2
- ARHGAP4 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs374827115, COSV100604177; called by muse, mutect2, varscan2
- ARHGAP45 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267605271, COSV100491062; called by muse, mutect2, varscan2
- ARHGEF2 | c.1199G>A p.R400H (on ENST00000361247 / NM_001162383.2; = p.R372H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1475947036, COSV58106020; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID3B | c.1063C>T p.L355F | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60558103, COSV60559184; called by muse, mutect2, varscan2
- ARMC4 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs754841451, COSV53467258, COSV99518997; called by muse, mutect2, varscan2
- ARSG | c.1328G>A p.S443N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs189928799, COSV100048599; called by muse, mutect2, varscan2
- ASCC3 | c.489dup p.G164Wfs*2 | Frame Shift Ins (INS) | VAF 7/11 reads (64%) | catalogued as rs747570359; called by mutect2, varscan2
- ASPM | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs200881457, COSV54125536; called by muse, mutect2, varscan2
- ATP11C | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV100558499; called by muse, mutect2, varscan2
- ATP5MPL | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99744041; called by muse, mutect2, varscan2
- AXIN1 | c.1523del p.G508Vfs*197 | Frame Shift Del (DEL) | VAF 93/229 reads (41%) | catalogued as rs760961378; called by mutect2, pindel, varscan2
- B3GNTL1 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as rs776592296, COSV100302209; called by muse, mutect2, varscan2
- B4GALNT4 | c.2887G>T p.G963C | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100327841; called by muse, mutect2
- B4GALT2 | c.21del p.T8Rfs*102 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as rs759490732, COSV99356264; called by mutect2, pindel, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 19/41 reads (46%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 42/117 reads (36%) | catalogued as rs779566914, COSV58300788; called by mutect2, pindel, varscan2
- BMP6 | c.1259G>A p.S420N | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1245865614, COSV99307388; called by muse, mutect2, varscan2
- BMPER | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99780406; called by muse, mutect2, varscan2
- BRINP3 | c.897G>A p.M299I | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as rs1182629607, COSV100818521; called by muse, mutect2
- BRS3 | c.1129A>G p.I377V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs749800437, COSV101036647; called by muse, mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 28/70 reads (40%) | catalogued as rs746043904; called by mutect2, varscan2
- BSX | c.568dup p.R190Pfs*? | Frame Shift Ins (INS) | VAF 25/76 reads (33%) | catalogued as rs759317554; called by mutect2, pindel, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | catalogued as rs774921343; called by mutect2, pindel, varscan2
- C16orf54 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs770832221, COSV100268565; called by muse, mutect2, varscan2
- C3orf38 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371557541; called by muse, mutect2, varscan2
- C3orf84 | c.612C>A p.S204R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs749697413, COSV100234312; called by muse, mutect2, varscan2
- C6orf58 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100315037; called by muse, mutect2
- CACNA1C | c.5566C>T p.P1856S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV100221759; called by muse, mutect2, varscan2
- CACNA1H | c.6727del p.D2243Tfs*19 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | catalogued as rs753624103; called by mutect2, pindel, varscan2
- CAPN12 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV99400680; called by muse, mutect2, varscan2
- CARNS1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs887962861, COSV100322202; called by muse, mutect2, varscan2
- CCDC14 | c.818G>A p.S273N (on ENST00000488653; = p.S225N on NM_022757.5) | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100113420; called by muse, mutect2, varscan2
- CCDC15 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs371097318; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC57 | c.379C>A p.H127N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101052069; called by muse, mutect2, varscan2
- CCM2L | c.141del p.D48Tfs*27 | Frame Shift Del (DEL) | VAF 24/67 reads (36%) | catalogued as COSV52949350; called by mutect2, pindel, varscan2
- CCT3 | c.610-2A>G p.X204_splice | Splice Site (SNP) | VAF 18/37 reads (49%) | catalogued as COSV99827485; called by muse, mutect2, varscan2
- CCT8L2 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.983); catalogued as COSV100743054; called by muse, mutect2, varscan2
- CD1D | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.446); catalogued as COSV100939649; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 20/41 reads (49%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH11 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99219587; called by muse, mutect2
- CDH23 | c.6376C>T p.R2126C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs776269225, COSV99034530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDKN3 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs762825170, COSV53593131; called by muse, mutect2, varscan2
- CDYL | c.1231C>T p.R411C (on ENST00000328908 / NM_001368125.1; = p.R357C on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs140950492; called by muse, mutect2, varscan2
- CELSR2 | c.2515G>A p.A839T | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99604631; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 32/68 reads (47%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP47 | c.5524G>A p.V1842M | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs748263281, COSV100545677, COSV57971446; called by muse, mutect2, varscan2
- CHAMP1 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.213); catalogued as rs781818310, COSV63521985; called by muse, mutect2, varscan2
- CHCHD5 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs200306063, COSV100260911; called by muse, mutect2, varscan2
- CHST1 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100346454; called by muse, mutect2, varscan2
- CKLF | c.447dup p.E150Rfs*12 (on ENST00000264001 / NM_016951.4; = p.E65Rfs*12 on NM_016326.3) | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs754415052; called by mutect2, varscan2
- CLBA1 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs201210390; called by muse, mutect2, varscan2
- CLIC6 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs996635682, COSV100659314; called by mutect2, varscan2
- CLMN | c.393A>G p.I131M | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs767403582, COSV100112837; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | catalogued as rs369752219; called by mutect2, varscan2
- CLSPN | c.1211dup p.N404Kfs*2 | Frame Shift Ins (INS) | VAF 27/80 reads (34%) | catalogued as rs1455213253; called by mutect2, pindel, varscan2
- COL15A1 | c.2480C>T p.P827L | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs2274961, COSV66644532; called by muse, mutect2, varscan2
- COL15A1 | c.2828del p.P943Lfs*7 | Frame Shift Del (DEL) | VAF 36/90 reads (40%) | catalogued as rs1449800304; called by mutect2, pindel, varscan2
- COL17A1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs754050269, COSV100793142; called by muse, mutect2, varscan2
- COL7A1 | c.7420C>T p.R2474C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs939213328, COSV100097504; called by muse, mutect2, varscan2
- CPT1B | c.751A>G p.M251V | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1437774396, COSV100376813; called by muse, mutect2, varscan2
- CRNKL1 | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs141413150; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 43/144 reads (30%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CUBN | c.9232C>T p.L3078F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV100913415; called by muse, mutect2, varscan2
- CUBN | c.9231G>T p.E3077D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100913416; called by muse, mutect2, varscan2
- CUTC | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369267471; called by muse, mutect2, varscan2
- CYP26A1 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV99814918; called by muse, mutect2
- CYP26A1 | c.17T>G p.L6R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99814919; called by muse, mutect2
- CYP4F2 | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99686276; called by muse, mutect2, varscan2
- CYSLTR1 | c.671dup p.N224Kfs*6 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | catalogued as rs766746913; called by mutect2, varscan2
- CYTH1 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV63119710; called by muse, mutect2, varscan2
- DAW1 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1412547475, COSV100006461; called by muse, mutect2, varscan2
- DCAF4L1 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100295478; called by muse, mutect2, varscan2
- DCTN3 | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99427021; called by muse, mutect2, varscan2
- DDI2 | c.20G>A p.C7Y | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV101416147; called by muse, mutect2, varscan2
- DDX39B | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs267600954, COSV100795270; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs778036194; called by mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs553532837; called by mutect2, varscan2
- DEPDC5 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 38/89 reads (43%) | catalogued as rs372718805; called by muse, mutect2, varscan2
- DHX34 | c.1840G>A p.V614I | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as rs746433421, COSV100169663, COSV60894878; called by muse, mutect2, varscan2
- DIAPH1 | c.2108dup p.P704Tfs*71 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | catalogued as rs771360300; called by mutect2, varscan2
- DMAP1 | c.1340A>G p.N447S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.07); catalogued as rs771876966, COSV100261831; called by muse, mutect2, varscan2
- DMTF1 | c.1244del p.N415Tfs*28 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | catalogued as rs1348399160; called by mutect2, pindel, varscan2
- DMXL2 | c.326del p.L109* | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs752363479; called by mutect2, varscan2
- DNAH8 | c.12334G>A p.G4112R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769556700, COSV59436429; called by muse, mutect2, varscan2
- DNAI1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs764486701, COSV99647109; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 56/88 reads (64%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK6 | c.3359C>T p.A1120V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99626537; called by muse, mutect2, varscan2
- DOCK9 | c.2748C>T p.Y916= (on ENST00000376460 / NM_001366676.2; = p.Y917= on NM_015296.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 46/118 reads (39%) | catalogued as rs779438223, COSV59624175; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- EEFSEC | c.599A>G p.Q200R | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.374); catalogued as COSV99631249, COSV99631686; called by muse, mutect2, varscan2
- EFEMP1 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as rs752116761, COSV62616945; called by muse, mutect2, varscan2
- EGR1 | c.802A>G p.T268A | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99525579; called by muse, mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs1377283633; called by mutect2, varscan2
- EMC1 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs971300635, COSV64346232; called by muse, mutect2, varscan2
- EMILIN1 | c.2206C>T p.R736W | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs139887250; called by muse, mutect2, varscan2
- EMSY | c.3332G>A p.R1111H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs762190281, COSV100596017; called by muse, varscan2
- ENTR1 | c.652C>A p.P218T (on ENST00000357365 / NM_001039707.2; = p.P195T on NM_006643.4) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.076); catalogued as rs772749560, COSV100048373; called by muse, mutect2, varscan2
- EOLA2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100778103; called by muse, mutect2, varscan2
- EPHA2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs758092063, COSV100626263; called by muse, mutect2, varscan2
- EPHB2 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs750776222, COSV65862752, COSV65867179; called by muse, mutect2, varscan2
- EPN3 | c.795del p.M266Wfs*28 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | catalogued as COSV99277330; called by mutect2, pindel, varscan2
- FABP2 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs142649876, COSV99916984; called by muse, varscan2
- FAM47A | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.099); catalogued as rs568669965, COSV100650039; called by muse, mutect2, varscan2
- FAM47B | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs370213556, COSV61453664; called by muse, mutect2, varscan2
- FAXC | c.824-2A>G p.X275_splice | Splice Site (SNP) | VAF 21/40 reads (53%) | catalogued as COSV101067237; called by muse, mutect2, varscan2
- FBXO36 | c.383G>A p.C128Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1378857071, COSV99391847; called by muse, mutect2, varscan2
- FBXO38 | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs530698536, COSV99693885; called by muse, mutect2, varscan2
- FCGRT | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99571407; called by muse, mutect2, varscan2
- FFAR3 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 48/153 reads (31%) | catalogued as COSV100588291; called by muse, mutect2, varscan2
- FHOD3 | c.2032A>G p.M678V (on ENST00000359247 / NM_001281739.3; = p.M695V on NM_025135.5) | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV99942642; called by muse, mutect2, varscan2
- FLNC | c.4924A>G p.T1642A | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV100368642; called by muse, mutect2
- FLOT2 | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV101204804; called by muse, mutect2, varscan2
- FMNL1 | c.1561del p.V521Cfs*99 | Frame Shift Del (DEL) | VAF 8/15 reads (53%) | catalogued as COSV58955516; called by mutect2, varscan2
- FMR1 | c.1062dup p.H355Tfs*15 | Frame Shift Ins (INS) | VAF 18/65 reads (28%) | catalogued as rs781892436; called by mutect2, varscan2
- FNDC1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs376877270; called by muse, mutect2, varscan2
- FREM1 | c.6069del p.F2023Lfs*45 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | catalogued as COSV101083523; called by mutect2, pindel, varscan2
- FZD6 | c.386G>A p.C129Y | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV100708483; called by muse, mutect2, varscan2
- GALNT17 | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV100355907, COSV61153893; called by muse, mutect2, varscan2
- GBA2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.659); catalogued as rs1000532303, COSV100803481; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 44/124 reads (35%) | catalogued as rs548474277; called by mutect2, varscan2
- GHRH | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as rs762180006, COSV99411221; called by muse, mutect2, varscan2
- GID8 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1167456469, COSV99824179; called by muse, mutect2, varscan2
- GLIPR1 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99875855; called by muse, mutect2, varscan2
- GLIS3 | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs934809482, COSV100174720; called by muse, mutect2, varscan2
- GNAT1 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV99222503; called by muse, mutect2, varscan2
- GOLM2 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV100248036; called by muse, mutect2, varscan2
- GPC5 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as rs1483462626, COSV100995643; called by muse, mutect2, varscan2
- GPRIN1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs764550111, COSV99992125; called by muse, mutect2, varscan2
- GRHL1 | c.737G>T p.S246I | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.222); catalogued as COSV100258131; called by muse, mutect2, varscan2
- GRIK5 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181684922, COSV99491283; called by muse, mutect2
- GTF3C4 | c.1921A>G p.K641E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV100936076; called by muse, mutect2, varscan2
- HBA1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV99285432; called by mutect2, varscan2
- HCN4 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs760413254, COSV99983529; called by muse, mutect2, varscan2
- HDAC5 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV99870995; called by muse, mutect2, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as COSV100625709; called by mutect2, varscan2
- HELZ2 | c.6616del p.R2206Vfs*29 (on ENST00000467148 / NM_001037335.2; = p.R1637Vfs*29 on NM_033405.3) | Frame Shift Del (DEL) | VAF 16/23 reads (70%) | catalogued as rs745497383, COSV101427649; called by mutect2, varscan2
- HERC1 | c.1704T>G p.C568W | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101496844, COSV71249534; called by muse, mutect2, varscan2
- HEXD | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100027981; called by muse, mutect2, varscan2
- HIC2 | c.36del p.W13Gfs*24 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | catalogued as COSV68042747; called by mutect2, pindel, varscan2
- HIC2 | c.481del p.R161Afs*113 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs745918762; called by mutect2, varscan2
- HK2 | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770307123, COSV51875232; called by muse, mutect2, varscan2
- HLTF | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs372238111, COSV100027082; called by muse, mutect2, varscan2
- HPS3 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 30/55 reads (55%) | catalogued as COSV99937587; called by muse, mutect2, varscan2
- HPS6 | c.1789del p.A597Qfs*16 | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | catalogued as rs1383241620; called by mutect2, pindel, varscan2
- HPSE2 | c.1723A>G p.T575A | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100986182; called by muse, mutect2, varscan2
- HPSE2 | c.761_763del p.N254del | In Frame Del (DEL) | VAF 32/88 reads (36%) | catalogued as rs775252263; called by pindel, varscan2
- HSD17B14 | c.743del p.G248Vfs*35 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as COSV54414601; called by mutect2, pindel, varscan2
- HSF2BP | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778782225, COSV99375725; called by muse, mutect2, varscan2
- HTR1A | c.1070G>A p.C357Y | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100109255; called by muse, mutect2, varscan2
- HTRA1 | c.1120+2T>C p.X374_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100934793; called by muse, mutect2, varscan2
- HUWE1 | c.12235G>A p.A4079T | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99473960; called by muse, mutect2, varscan2
- IFIH1 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs191839015, COSV99718817; called by muse, mutect2, varscan2
- IGF2R | c.2282C>A p.P761Q | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201251256, COSV100808065; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs760021495; called by mutect2, varscan2
- IL3 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | PolyPhen benign (0); catalogued as rs780057953, COSV57309631; called by muse, mutect2, varscan2
- INSR | c.3362A>G p.E1121G | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100253274; called by muse, mutect2, varscan2
- INTS9 | c.264G>A p.T88= | Splice Region (SNP) | VAF 8/22 reads (36%) | catalogued as rs763295626, COSV68436461; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 35/87 reads (40%) | catalogued as rs1561359523; called by mutect2, varscan2
- IPPK | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.6); catalogued as COSV99845830; called by muse, mutect2, varscan2
- ITGB2 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs752291593, COSV56610349, COSV56610568; called by muse, mutect2, varscan2
- ITPR1 | c.2263G>A p.E755K (on ENST00000354582; = p.E740K on NM_002222.7) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV56996351; called by muse, mutect2, varscan2
- JAK1 | c.1274C>T p.T425I | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as COSV100692294; called by muse, mutect2, varscan2
- JAK3 | c.2960G>A p.G987D | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV71688230; called by muse, mutect2, varscan2
- JPH3 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs376022547; called by muse, mutect2, varscan2
- JSRP1 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99678482; called by muse, mutect2, varscan2
- KCNC3 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.02); catalogued as rs748015812, COSV100979370; called by muse, mutect2, varscan2
- KCNJ5 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs1356200702, COSV100610797; called by muse, mutect2, varscan2
- KCNK4 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV100487409; called by muse, mutect2, varscan2
- KIAA1549L | c.4784C>T p.P1595L (on ENST00000321505; = p.P1892L on NM_012194.3) | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762094891, COSV100382222; called by muse, mutect2, varscan2
- KIDINS220 | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs200581891; called by muse, mutect2, varscan2
- KIF22 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as rs776995863, COSV99361442; called by muse, mutect2, varscan2
- KLHL11 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.853); catalogued as rs918645733, COSV59862706, COSV59863201; called by muse, mutect2, varscan2
- KMT2D | c.8437C>T p.Q2813* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99985349; called by muse, mutect2, varscan2
- KNDC1 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs370092960; called by muse, mutect2, varscan2
- KRT34 | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as rs1314977614, COSV101222715; called by muse, mutect2, varscan2
- KRT4 | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV99543177; called by muse, mutect2, varscan2
- KRT72 | c.241A>G p.S81G | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV99537456; called by muse, mutect2, varscan2
- KRTAP10-3 | c.65G>T p.C22F | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100555281; called by muse, mutect2, varscan2
- L1CAM | c.3385G>A p.A1129T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100649437; called by muse, mutect2, varscan2
- LAMA4 | c.3699A>G p.I1233M (on ENST00000230538 / NM_001105206.3; = p.I1226M on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100039278; called by muse, mutect2, varscan2
- LAMP1 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs755522116, COSV100208755; called by mutect2, varscan2
- LIPC | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs142388191, COSV100134831; called by muse, mutect2, varscan2
- LIPI | c.1427G>A p.C476Y | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753964; called by muse, mutect2, varscan2
- LOXL4 | c.594C>G p.N198K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.936); catalogued as COSV99584154; called by muse, mutect2, varscan2
- LRP1 | c.4904G>A p.R1635Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as rs766682074, COSV54503077; called by muse, mutect2, varscan2
- LRP1 | c.6553G>T p.G2185W | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54524395, COSV99677007; called by muse, mutect2, varscan2
- LRP1 | c.10405del p.R3469Gfs*24 | Frame Shift Del (DEL) | VAF 32/93 reads (34%) | catalogued as COSV54520204; called by mutect2, pindel, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 32/73 reads (44%) | catalogued as rs757410385; called by mutect2, varscan2
- LRRC37A3 | c.3580C>T p.Q1194* | Nonsense Mutation (SNP) | VAF 54/128 reads (42%) | catalogued as COSV100141457; called by muse, mutect2, varscan2
- LRRC7 | c.1586G>T p.G529V (on ENST00000651989 / NM_001370785.2; = p.G496V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.093); catalogued as COSV99229372; called by muse, mutect2, varscan2
- LRRN2 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs766846193, COSV100912936, COSV65784549; called by muse, mutect2, varscan2
- LTBP3 | c.1951G>A p.V651M | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs1190589964, COSV100100265; called by muse, mutect2, varscan2
- MAGEA8 | c.632T>C p.M211T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99674777; called by muse, mutect2, varscan2
- MAGED1 | c.524G>A p.S175N | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.007); catalogued as rs1014916789, COSV100431785; called by muse, mutect2, varscan2
- MAP1B | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV99702881; called by muse, mutect2, varscan2
- MAP3K1 | c.1850del p.G617Efs*39 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | catalogued as CM108514; called by mutect2, pindel, varscan2
- MAP3K1 | c.4073C>T p.S1358L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV101267095; called by muse, mutect2, varscan2
- MAP3K19 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs867086972, COSV100209138; called by muse, mutect2, varscan2
- MBD4 | c.939del p.E314Kfs*4 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs558765093; called by mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs750092100; called by mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as rs780635289; called by mutect2, varscan2
- MIA2 | c.176del p.L59Cfs*22 | Frame Shift Del (DEL) | VAF 56/156 reads (36%) | catalogued as rs769553721, COSV54495286; called by mutect2, varscan2
- MIS18BP1 | c.471del p.K157Nfs*24 | Frame Shift Del (DEL) | VAF 59/112 reads (53%) | catalogued as rs546807245; called by mutect2, varscan2
- MKKS | c.1083dup p.H362Sfs*5 | Frame Shift Ins (INS) | VAF 24/50 reads (48%) | catalogued as COSV100726337; called by mutect2, varscan2
- MME | c.1400dup p.R468Efs*3 | Frame Shift Ins (INS) | VAF 12/33 reads (36%) | catalogued as rs751149568; called by mutect2, pindel, varscan2
- MORN1 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as rs774314148, COSV58101035; called by muse, mutect2, varscan2
- MOV10L1 | c.3329G>A p.R1110Q | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757521598, COSV99434931; called by muse, mutect2, varscan2
- MPP5 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1352763103, COSV99907363; called by muse, mutect2, varscan2
- MROH2B | c.4114del p.I1372Sfs*5 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | catalogued as rs756600463; called by mutect2, varscan2
- MTG2 | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100895198, COSV63694475; called by muse, mutect2, varscan2
- MTUS2 | c.2723G>A p.R908Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs542576593, COSV54984176, COSV99685789; called by muse, mutect2, varscan2
- MUC1 | c.3249+1G>A p.X1083_splice (on ENST00000611571 / NM_001371720.1; = p.X94_splice on NM_002456.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100104792; called by muse, mutect2, varscan2
- MYBPC1 | c.704G>A p.R235H (on ENST00000550270 / NM_206820.2; = p.R260H on NM_002465.4) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99053745; called by muse, mutect2
- MYH1 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 50/116 reads (43%) | catalogued as rs1414711341, COSV99820831; called by muse, mutect2, varscan2
- MYH11 | c.5072A>G p.Q1691R | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.044); catalogued as COSV100260067; called by muse, mutect2, varscan2
- MYH6 | c.5803dup p.M1935Nfs*4 | Frame Shift Ins (INS) | VAF 24/56 reads (43%) | catalogued as rs768525215; called by mutect2, pindel, varscan2
- MYO16 | c.3478G>T p.G1160* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as COSV100697191; called by muse, mutect2, varscan2
- MYT1L | c.2569del p.E857Rfs*2 | Frame Shift Del (DEL) | VAF 31/81 reads (38%) | catalogued as COSV67732344; called by mutect2, pindel, varscan2
- NAAA | c.766del p.R256Gfs*19 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs34351680, COSV54432217; called by mutect2, pindel, varscan2
- NBEAL2 | c.4271G>A p.S1424N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99437392; called by muse, mutect2, varscan2
- NCBP1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs763319595, COSV100912669; called by muse, mutect2, varscan2
- NCOR2 | c.3178del p.R1060Vfs*3 | Frame Shift Del (DEL) | VAF 34/80 reads (43%) | catalogued as rs749518211, COSV100656528, COSV62300840; called by mutect2, varscan2
- NCOR2 | c.2956dup p.R986Pfs*76 | Frame Shift Ins (INS) | VAF 28/72 reads (39%) | catalogued as rs746871841; called by mutect2, varscan2
- NEK9 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as COSV99464470; called by muse, varscan2
- NFYC | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100438693; called by muse, mutect2, varscan2
- NGFR | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs759647765, COSV50801695; called by muse, mutect2, varscan2
- NLGN4X | c.1286A>G p.D429G | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); catalogued as COSV99323642; called by muse, mutect2, varscan2
- NLRC5 | c.3905G>A p.R1302Q | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs199476000, COSV52665175; ClinVar: not provided; called by muse, mutect2, varscan2
- NME8 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs751830410, COSV52246254; called by muse, mutect2, varscan2
- NMT1 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV99364958; called by muse, mutect2, varscan2
- NOL11 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs751845847, COSV99475252; called by muse, varscan2
- NOP53 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs777866172, COSV55882087; called by muse, mutect2, varscan2
- NPAT | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as COSV99586305; called by muse, mutect2, varscan2
- NPHP1 | c.2031_2033del p.E678del (on ENST00000393272 / NM_207181.4; = p.E679del on NM_000272.5) | In Frame Del (DEL) | VAF 36/97 reads (37%) | catalogued as rs769266828; called by pindel, varscan2
- NRCAM | c.2143G>A p.V715M (on ENST00000379028 / NM_001371124.1; = p.V699M on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs772374105, COSV100695345; called by muse, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 43/128 reads (34%) | catalogued as rs754860965; called by mutect2, varscan2
- NTRK3 | c.1145del p.N382Tfs*32 | Frame Shift Del (DEL) | VAF 47/160 reads (29%) | catalogued as COSV58121797, COSV58130978; called by mutect2, pindel, varscan2
- NYAP2 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs375727693; called by muse, mutect2, varscan2
- NYNRIN | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767253660, COSV66842596; called by muse, mutect2, varscan2
- OBSCN | c.10038_10039dup p.G3347Vfs*20 | Frame Shift Ins (INS) | VAF 23/66 reads (35%) | catalogued as rs772869624; called by mutect2, varscan2
- OBSL1 | c.1112C>G p.T371R | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777770619, COSV99216596, COSV99217398; called by muse, mutect2, varscan2
- OFD1 | c.2896C>T p.Q966* | Nonsense Mutation (SNP) | VAF 25/43 reads (58%) | catalogued as COSV100366488; called by muse, mutect2, varscan2
- OPLAH | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs781912279, COSV101470901; called by muse, mutect2, varscan2
- OR10K2 | c.934T>A p.L312M | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as COSV100149636, COSV59220817; called by muse, mutect2, varscan2
- OR1L6 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100490981, COSV59028748; called by muse, mutect2, varscan2
- OSBPL6 | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); catalogued as rs146931219, COSV51918300; called by muse, varscan2
- OSMR | c.1049T>C p.I350T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99953640; called by muse, mutect2, varscan2
- PABPC3 | c.1679G>T p.R560L | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV99879980; called by muse, mutect2, varscan2
- PAM | c.607A>G p.M203V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV99173792; called by muse, mutect2, varscan2
- PAOX | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs747718413, COSV53374905, COSV99529669; called by muse, mutect2, varscan2
- PAXIP1 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101250033; called by muse, mutect2, varscan2
- PCDH15 | c.2158T>C p.Y720H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.629); catalogued as COSV100226597; called by muse, mutect2
- PCDHA6 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100971749, COSV65343910; called by muse, mutect2, varscan2
- PCDHB10 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as rs782288188, COSV53378674; called by muse, mutect2, varscan2
- PCDHGA5 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.022); catalogued as COSV99545687; called by muse, mutect2, varscan2
- PCIF1 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV100976113; called by muse, mutect2, varscan2
- PDE3A | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100762719; called by muse, mutect2, varscan2
- PDE9A | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs1479153246, COSV99371010; called by muse, mutect2, varscan2
- PDZD4 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51245288, COSV99381354; called by muse, mutect2
- PEPD | c.1271A>G p.E424G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV99728637; called by muse, mutect2
- PHF12 | c.2011A>G p.T671A | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV99256166; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs769717544; called by mutect2, varscan2
- PIGT | c.1043dup p.V349Sfs*99 | Frame Shift Ins (INS) | VAF 21/50 reads (42%) | catalogued as rs749895437; called by mutect2, varscan2
- PKD1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs958271752, COSV99238928; called by muse, mutect2, varscan2
- PKP2 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs755215178, COSV50742789, COSV99298396; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PLA2G15 | c.593G>C p.S198T | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99547348; called by muse, mutect2, varscan2
- PLA2G2E | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV100908831; called by muse, mutect2, varscan2
- PLXNA3 | c.5167C>T p.R1723C | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782704287, COSV100859846; called by muse, mutect2, varscan2
- POLD1 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs200679966, COSV101486918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPARD | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV100283310; called by muse, mutect2, varscan2
- PPM1F | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201182279, COSV99601680; called by muse, mutect2, varscan2
- PPM1L | c.256T>C p.W86R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101534468; called by muse, mutect2, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 16/35 reads (46%) | catalogued as rs540232176; called by mutect2, varscan2
- PPP4R2 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs375800683; called by muse, mutect2, varscan2
- PRR35 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs780446928, COSV99552249; called by muse, mutect2, varscan2
- PRSS53 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375149743, COSV99762597; called by muse, mutect2, varscan2
- PSD | c.676del p.R226Gfs*68 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | catalogued as rs772089836; called by mutect2, pindel, varscan2
- PSD4 | c.1451C>T p.T484I | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV99831423; called by muse, mutect2
- PSMA6 | c.684-1G>T p.X228_splice | Splice Site (SNP) | VAF 15/30 reads (50%) | catalogued as COSV99809276; called by muse, mutect2, varscan2
- PSPN | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as rs367629407; called by mutect2, varscan2
- PTGFRN | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.632); catalogued as COSV101277451; called by muse, mutect2, varscan2
- PTH1R | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV100481152; called by muse, mutect2, varscan2
- PTPN13 | c.3013C>T p.H1005Y | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV100365349; called by muse, mutect2, varscan2
- PTPN6 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as rs782761798, COSV100016975; called by muse, mutect2, varscan2
- PTPRE | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV99618908; called by muse, mutect2, varscan2
- PTPRO | c.2750C>T p.P917L (on ENST00000281171 / NM_030667.3; = p.P889L on NM_002848.4) | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs568440293, COSV99840148; called by muse, mutect2, varscan2
- PTTG2 | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as COSV99792048; called by muse, mutect2, varscan2
- PUM2 | c.2429T>A p.M810K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV100163940; called by muse, mutect2, varscan2
- PVRIG | c.236del p.G79Afs*245 | Frame Shift Del (DEL) | VAF 64/178 reads (36%) | catalogued as rs768997455; called by mutect2, varscan2
- QARS1 | c.679del p.E227Rfs*24 | Frame Shift Del (DEL) | VAF 26/63 reads (41%) | catalogued as rs772343264; called by mutect2, pindel, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs755727862; called by mutect2, varscan2
- RAB20 | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV99940929; called by muse, mutect2, varscan2
- RAB3IL1 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs148671281, COSV57117754; called by muse, mutect2, varscan2
- RAD54L2 | c.1515G>A p.M505I | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99621753; called by muse, mutect2, varscan2
- RASGRP4 | c.633C>G p.Y211* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as COSV99498791; called by muse, mutect2, varscan2
- RBBP8NL | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | catalogued as COSV99436941; called by muse, mutect2, varscan2
- RBM42 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as COSV52897007; called by muse, mutect2, varscan2
- RIN1 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.012); catalogued as COSV100254932; called by muse, mutect2, varscan2
- RIPK4 | c.909del p.E305Kfs*13 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | catalogued as COSV100204646; called by pindel, varscan2
- RNASEH2B | c.925del p.I309Lfs*26 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | catalogued as rs75254367; ClinVar: benign / likely benign; called by mutect2, varscan2
- RNF31 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs972151680, COSV100142060; called by muse, mutect2
- RPA1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV54611929; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 24/40 reads (60%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RSL1D1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV100852007; called by muse, mutect2, varscan2
- RTL3 | c.929C>A p.P310H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100330051; called by muse, mutect2, varscan2
- RTL3 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); catalogued as COSV58183123; called by muse, varscan2
- RUNX1 | c.491G>A p.R164K (on ENST00000344691 / NM_001001890.3; = p.R191K on NM_001754.5) | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV100278256, COSV55882222; called by muse, mutect2, varscan2
- RYR1 | c.6263A>T p.E2088V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV100616798; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs765867975; called by mutect2, varscan2
- SBSPON | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99817723; called by muse, mutect2, varscan2
- SCG2 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778138097, COSV59539663; called by muse, mutect2, varscan2
- SCN4A | c.1523G>A p.G508D | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.218); catalogued as COSV101438632; called by muse, mutect2, varscan2
- SEC31A | c.389T>C p.V130A | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV100307972; called by muse, mutect2, varscan2
- SEMA5B | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1380044749, COSV99533015; called by muse, mutect2, varscan2
- SETDB1 | c.3032A>G p.E1011G | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV99645729; called by muse, mutect2, varscan2
- SF3B2 | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100488623; called by muse, mutect2, varscan2
- SHANK2 | c.4095del p.E1366Sfs*20 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as COSV53620910; called by mutect2, pindel, varscan2
- SIGLEC1 | c.3652G>A p.A1218T | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.848); catalogued as COSV99170462; called by muse, mutect2, varscan2
- SIGLEC6 | c.842del p.P281Lfs*4 | Frame Shift Del (DEL) | VAF 48/139 reads (35%) | catalogued as COSV100585657; called by mutect2, pindel, varscan2
- SIK3 | c.1624C>T p.R542W (on ENST00000445177 / NM_001366686.2; = p.R548W on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250419938, COSV99408702; called by muse, mutect2, varscan2
- SIN3A | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as COSV64582043; called by muse, mutect2, varscan2
- SIRT3 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as COSV100728910; called by muse, mutect2
- SIRT7 | c.536C>A p.P179Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs567589929, COSV100155711, COSV58711732; called by muse, mutect2, varscan2
- SIX4 | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV99382473; called by muse, mutect2, varscan2
- SLC11A1 | c.1081C>A p.L361I | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV99262407; called by muse, mutect2, varscan2
- SLC12A3 | c.2524C>A p.L842I (on ENST00000563236 / NM_001126108.2; = p.L851I on NM_000339.3) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99344662; called by muse, mutect2, varscan2
- SLC25A10 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV100519100; called by muse, mutect2
- SLC2A10 | c.919A>G p.M307V | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs767671973, COSV100826401; called by muse, mutect2, varscan2
- SLC2A2 | c.1438A>G p.T480A | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV100049489; called by muse, mutect2, varscan2
- SLC39A10 | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779765683, COSV62767121, COSV62769432; called by muse, mutect2, varscan2
- SLC39A10 | c.1391A>G p.Q464R | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.339); catalogued as COSV100660750; called by muse, mutect2, varscan2
- SLC5A1 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as COSV56688458; called by muse, mutect2, varscan2
- SLC66A1 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV100913326; called by muse, mutect2, varscan2
- SLC7A3 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1380220296, COSV99979817; called by muse, mutect2, varscan2
- SLC7A9 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as HM070069, COSV50097059; called by muse, mutect2, varscan2
- SLIT1 | c.4028G>A p.R1343H | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1436958392, COSV56581414; called by muse, mutect2, varscan2
- SLX4 | c.1406del p.P469Hfs*4 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as rs774532876; called by pindel, varscan2
- SMC2 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs367564983; called by muse, mutect2, varscan2
- SMOX | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99603566; called by muse, mutect2, varscan2
- SNX25 | c.2383G>T p.G795C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53015021, COSV99253377; called by muse, mutect2, varscan2
- SNX29 | c.1484T>G p.L495R | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100029986; called by muse, mutect2, varscan2
- SOX10 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100329861; called by muse, mutect2, varscan2
- SOX10 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV100329862; called by muse, mutect2, varscan2
- SPEM2 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1444183270, COSV60367030; called by muse, mutect2, varscan2
- SPEN | c.9395G>A p.R3132K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.383); catalogued as COSV101005545; called by muse, mutect2, varscan2
- SPRR2D | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 128/278 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV100836077; called by muse, mutect2, varscan2
- SRRM3 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV100418871; called by muse, mutect2, varscan2
- SSR2 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99828684; called by muse, mutect2, varscan2
- STAB1 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as COSV58738057; called by muse, mutect2, varscan2
- STAU1 | c.932G>A p.R311Q (on ENST00000371856 / NM_001319135.1; = p.R230Q on NM_004602.3) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs779504339, COSV100574554; called by muse, mutect2, varscan2
- STK40 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs753570647, COSV100828721; called by muse, mutect2, varscan2
- SUGP2 | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs375344970; called by muse, mutect2, varscan2
- SUPT5H | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV100782141; called by muse, mutect2, varscan2
- SYNE2 | c.9044C>T p.S3015L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100648390; called by muse, mutect2, varscan2
- TBC1D22A | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs756141681, COSV100453662, COSV61437609; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 18/25 reads (72%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D4 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs567936519, COSV100884774; called by muse, mutect2, varscan2
- TBCD | c.3043G>A p.D1015N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); catalogued as rs375899767; called by muse, mutect2, varscan2
- TCF19 | c.72del p.A25Pfs*72 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as rs751224053; called by mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM1 | c.2063C>A p.S688Y | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV100950769; called by muse, mutect2, varscan2
- TENM3 | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs376900105; called by muse, varscan2
- TEX13A | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as rs1307987026, COSV61172451; called by muse, mutect2, varscan2
- TGM6 | c.1433del p.G478Vfs*25 | Frame Shift Del (DEL) | VAF 50/154 reads (32%) | catalogued as COSV52479555; called by mutect2, pindel, varscan2
- THBS2 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs749837715, COSV64682587; called by muse, mutect2, varscan2
- THEG | c.198del p.E67Rfs*50 | Frame Shift Del (DEL) | VAF 38/106 reads (36%) | catalogued as rs778028490; called by mutect2, pindel, varscan2
- THOP1 | c.2034G>T p.Q678H | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100310762; called by muse, mutect2, varscan2
- THRAP3 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.79); catalogued as COSV100663565; called by muse, mutect2, varscan2
- TJP3 | c.2484del p.Y830Tfs*64 | Frame Shift Del (DEL) | VAF 33/117 reads (28%) | catalogued as rs748320679, COSV99515633; called by mutect2, pindel, varscan2
- TLR8 | c.1258C>A p.L420M (on ENST00000218032 / NM_138636.5; = p.L438M on NM_016610.4) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99487249; called by muse, mutect2, varscan2
- TMC7 | c.1420T>C p.C474R | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1343681974, COSV100432778; called by muse, mutect2, varscan2
- TMCO3 | c.1577G>A p.C526Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100952420; called by muse, mutect2, varscan2
- TMEM129 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100304955; called by muse, mutect2, varscan2
- TMEM132A | c.1487C>T p.P496L (on ENST00000453848 / NM_178031.3; = p.P497L on NM_017870.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99136979; called by muse, mutect2
- TMEM215 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100713232; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 38/74 reads (51%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM8B | c.1013T>G p.L338R | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100941720; called by muse, mutect2, varscan2
- TNFRSF10C | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100790561; called by muse, mutect2
- TOX | c.857C>A p.A286D | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100813077; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs763112993; called by mutect2, varscan2
- TRIM73 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs201374916, COSV60455663, COSV60455938; called by muse, mutect2, varscan2
- TRMT6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs766784956, COSV52544184, COSV99177609; called by muse, mutect2, varscan2
- TRPV4 | c.1243T>C p.Y415H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.132); catalogued as COSV99925006; called by muse, mutect2, varscan2
- TSHZ2 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs930326171, COSV61587378, COSV61590906; called by muse, mutect2, varscan2
- TSSK3 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as rs373563571; called by muse, mutect2, varscan2
- TTLL5 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100091398; called by muse, mutect2, varscan2
- TTLL8 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774158813, COSV99838585; called by muse, mutect2, varscan2
- TTN | c.96179T>C p.V32060A (on ENST00000591111; = p.V24636A on NM_003319.4) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | PolyPhen benign (0.119); catalogued as rs962659, COSV100626957; called by muse, mutect2, varscan2
- TTN | c.52273G>A p.V17425I (on ENST00000591111; = p.V10001I on NM_003319.4) | Missense Mutation (SNP) | VAF 28/93 reads (30%) | PolyPhen benign (0.006); catalogued as rs1308704992, COSV100626963; called by muse, mutect2, varscan2
- TTN | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | PolyPhen possibly damaging (0.688); catalogued as rs754182768, COSV60080671; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBB4A | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.292); catalogued as COSV99900136; called by muse, mutect2, varscan2
- TUBB4B | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100458153; called by muse, mutect2, varscan2
- TUBGCP3 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV56185398; called by muse, mutect2, varscan2
- TULP1 | c.628T>C p.S210P | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100004358; called by muse, mutect2, varscan2
- TUT1 | c.1859C>G p.T620S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.084); catalogued as COSV99545562; called by muse, mutect2, varscan2
- UBE2E3 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as rs772827469, COSV66583894; called by mutect2, varscan2
- UBR4 | c.10514C>T p.T3505I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs762918041, COSV100921654; called by muse, mutect2, varscan2
- UBTD1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs773272741, COSV100081033; called by muse, mutect2, varscan2
- UFSP2 | c.623dup p.N208Kfs*20 | Frame Shift Ins (INS) | VAF 15/52 reads (29%) | catalogued as rs1252058978; called by mutect2, varscan2
- UGDH | c.1250G>T p.W417L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100328578; called by muse, mutect2, varscan2
- UGT1A9 | c.364del p.S122Qfs*12 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs773627969; called by mutect2, pindel, varscan2
- UNC79 | c.1412G>A p.R471Q (on ENST00000393151 / NM_001346218.2; = p.R294Q on NM_020818.5) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.62); catalogued as rs752622200, COSV56396762, COSV99825496; called by muse, varscan2
- UPP2 | c.713del p.K238Sfs*2 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | catalogued as rs759424183; called by mutect2, pindel, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs762976381; called by mutect2, varscan2
- VPS33A | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs138934995; called by muse, mutect2, varscan2
- VPS54 | c.1459A>G p.R487G | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.05); catalogued as rs769500959, COSV99708648; called by muse, mutect2, varscan2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | catalogued as rs756173793; called by mutect2, varscan2
- WDFY3 | c.3238G>A p.D1080N | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV55708928, COSV99885359; called by muse, mutect2, varscan2
- WDR47 | c.2260C>T p.H754Y (on ENST00000369962 / NM_001142551.2; = p.H755Y on NM_014969.5) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100728433; called by muse, mutect2, varscan2
- WDR62 | c.3447C>T p.H1149= | Splice Region (SNP) | VAF 22/60 reads (37%) | catalogued as rs1228998070, COSV99544157; called by muse, mutect2, varscan2
- WNT2 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99626340; called by muse, mutect2, varscan2
- XIAP | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV100848949; called by muse, mutect2, varscan2
- XKR7 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.489); catalogued as rs147437006; called by muse, mutect2, varscan2
- XYLT2 | c.1378A>G p.N460D | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99191089; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- YES1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs777211673, COSV58847726; called by muse, mutect2, varscan2
- ZBED4 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs949003382, COSV99351597; called by muse, mutect2, varscan2
- ZBTB33 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV58533600, COSV58534599; called by muse, mutect2, varscan2
- ZBTB46 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs780050104, COSV55508319; called by muse, mutect2, varscan2
- ZC3H3 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99368473; called by muse, mutect2, varscan2
- ZCCHC7 | c.1625del p.K542Sfs*9 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs760783608; called by mutect2, varscan2
- ZFHX3 | c.1589T>C p.I530T | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV99214407; called by muse, mutect2, varscan2
- ZFR | c.1074del p.E359Kfs*4 | Frame Shift Del (DEL) | VAF 56/121 reads (46%) | catalogued as rs751974853; called by mutect2, varscan2
- ZHX3 | c.2738A>G p.H913R | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.025); catalogued as COSV100476665; called by muse, mutect2, varscan2
- ZNF143 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100218005; called by muse, mutect2, varscan2
- ZNF197 | c.897_899del p.E300del | In Frame Del (DEL) | VAF 32/72 reads (44%) | catalogued as rs1311940605; called by pindel, varscan2
- ZNF281 | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs755695688, COSV54166585; called by muse, mutect2, varscan2
- ZNF318 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs1401504276, COSV100546471; called by muse, mutect2, varscan2
- ZNF410 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs764400438, COSV100206577; called by muse, mutect2, varscan2
- ZNF512B | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs370483162; called by muse, mutect2, varscan2
- ZNF571 | c.218T>C p.M73T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100143973; called by muse, mutect2, varscan2
- ZNF662 | c.1010G>A p.C337Y | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100066624; called by muse, mutect2, varscan2
- ZNF668 | c.1543dup p.Q515Pfs*41 | Frame Shift Ins (INS) | VAF 34/76 reads (45%) | catalogued as rs760397907; called by mutect2, varscan2
- ZNF765 | c.1163G>A p.C388Y | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs895541945, COSV101125553; called by muse, mutect2, varscan2
- ZNF784 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV57596240; called by muse, mutect2, varscan2
- ZNF800 | c.650A>G p.D217G | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99758169; called by muse, mutect2, varscan2
- ZNF831 | c.2132G>A p.G711E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV64039064; called by muse, mutect2, varscan2
- ZRANB3 | c.883del p.I295* | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | catalogued as COSV99922299; called by mutect2, pindel, varscan2
- ADGRB2 | c.3018_3020del p.F1007del | In Frame Del (DEL) | VAF 22/52 reads (42%) | called by pindel, varscan2
- ADORA1 | c.364del p.R122Gfs*7 | Frame Shift Del (DEL) | VAF 31/95 reads (33%) | called by mutect2, pindel, varscan2
- AEBP1 | c.554del p.P185Hfs*107 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- AGA | c.1007del p.N336Ifs*29 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- AGO2 | c.51del p.I18Sfs*121 | Frame Shift Del (DEL) | VAF 33/101 reads (33%) | called by mutect2, pindel, varscan2
- AL592490.1 | c.238del p.V80Cfs*47 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- APOA4 | c.934dup p.E312Gfs*61 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- ARHGAP11A | c.375del p.F125Lfs*18 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- ARPP21 | c.1648_1649del p.X550_splice | Splice Site (DEL) | VAF 16/40 reads (40%) | called by pindel, varscan2
- ARRDC3 | c.768_770del p.S257del | In Frame Del (DEL) | VAF 16/56 reads (29%) | called by pindel, varscan2
- AXIN1 | c.234del p.T79Pfs*5 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- B3GAT2 | c.147del p.A50Pfs*49 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, varscan2
- BCLAF1 | c.859_861del p.S287del | In Frame Del (DEL) | VAF 9/89 reads (10%) | called by mutect2, pindel
- BIVM-ERCC5 | c.4067del p.N1356Ifs*4 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- BRWD3 | c.5118dup p.R1707Efs*12 | Frame Shift Ins (INS) | VAF 40/105 reads (38%) | called by mutect2, pindel, varscan2
- C1R | c.689del p.P230Lfs*100 (on ENST00000536053 / NM_001354346.2; = p.P216Lfs*100 on NM_001733.7) | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- CCDC184 | c.511del p.D171Tfs*76 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- CCND1 | c.852_866del p.C285_D289del | In Frame Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel
- CD79A | c.390del p.R131Gfs*61 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | called by mutect2, pindel, varscan2
- CECR2 | c.2520del p.N841Tfs*59 (on ENST00000342247 / NM_001290047.2; = p.N658Tfs*59 on NM_001290046.1) | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- CHSY1 | c.915del p.N306Tfs*15 | Frame Shift Del (DEL) | VAF 12/138 reads (9%) | called by mutect2, pindel
- CLCN4 | c.2043del p.E682Sfs*10 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | called by mutect2, pindel, varscan2
- CMTM1 | c.179_180dup p.I61Lfs*3 (on ENST00000457188 / NM_181269.3; = p.I178Lfs*3 on NM_052999.4) | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- CNPPD1 | c.971del p.P324Qfs*89 | Frame Shift Del (DEL) | VAF 32/64 reads (50%) | called by mutect2, pindel, varscan2
- COG6 | c.1237dup p.I413Nfs*5 | Frame Shift Ins (INS) | VAF 22/60 reads (37%) | called by mutect2, varscan2
- COPA | c.512del p.N171Tfs*11 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, varscan2
- CUX1 | c.1306del p.R436Afs*21 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- DEPDC5 | c.1310del p.N437Mfs*21 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | called by mutect2, pindel, varscan2
- DNAJC14 | c.1839_1840del p.H613Qfs*29 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | called by pindel, varscan2
- EIF2B4 | c.483del p.K161Nfs*32 (on ENST00000347454 / NM_001034116.2; = p.K160Nfs*32 on NM_015636.3) | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- ELOA | c.1210del p.T404Lfs*47 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- FAT4 | c.10470del p.S3491Qfs*9 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- FBXO28 | c.1049del p.K350Rfs*6 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- FOXJ1 | c.327del p.D110Tfs*11 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel
- FOXP4 | c.278_281del p.K93Sfs*14 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- GABRQ | c.1751del p.P584Qfs*109 | Frame Shift Del (DEL) | VAF 26/81 reads (32%) | called by mutect2, pindel, varscan2
- GJA10 | c.332del p.K111Sfs*21 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- GLRX2 | c.423_424del p.H141Qfs*18 (on ENST00000367439 / NM_197962.3; = p.H142Qfs*18 on NM_016066.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | called by pindel, varscan2
- GPBP1 | c.212del p.N71Mfs*14 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- GRIP2 | c.2731del p.Q911Rfs*8 (on ENST00000619221; = p.Q814Rfs*8 on NM_001080423.4) | Frame Shift Del (DEL) | VAF 51/132 reads (39%) | called by mutect2, pindel, varscan2
- HIKESHI | c.75del p.F25Lfs*46 | Frame Shift Del (DEL) | VAF 50/129 reads (39%) | called by mutect2, pindel, varscan2
- HNRNPK | c.942_944dup p.P315dup | In Frame Ins (INS) | VAF 13/39 reads (33%) | called by mutect2, varscan2
- HSPA4L | c.444del p.F148Lfs*9 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- ICA1 | c.970del p.S324Vfs*6 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- ICE1 | c.130del p.I44Lfs*8 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- IFNLR1 | c.168del p.F56Lfs*29 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- IL17RE | c.774del p.K258Nfs*34 | Frame Shift Del (DEL) | VAF 44/103 reads (43%) | called by mutect2, pindel, varscan2
- IL7R | c.799del p.R267Gfs*28 | Frame Shift Del (DEL) | VAF 82/226 reads (36%) | called by mutect2, pindel, varscan2
- ITPR2 | c.5405del p.K1802Sfs*13 | Frame Shift Del (DEL) | VAF 25/77 reads (32%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 50/60 reads (83%) | called by mutect2, varscan2
- KLF14 | c.594del p.F199Sfs*72 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, varscan2
- LAMC1 | c.2617del p.L873Wfs*20 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- MAP1A | c.7434del p.R2479Gfs*4 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.509_510del p.L170Qfs*8 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by pindel, varscan2
- METAP1 | c.711del p.F237Lfs*20 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | called by mutect2, pindel, varscan2
- MROH1 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- MYOCD | c.684del p.S229Afs*4 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- NEIL3 | c.1731del p.F577Lfs*23 | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- NELFE | c.18del p.G7Dfs*2 | Frame Shift Del (DEL) | VAF 45/113 reads (40%) | called by mutect2, pindel, varscan2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/89 reads (39%) | called by mutect2, pindel, varscan2
- NPY1R | c.1123del p.I375Sfs*24 | Frame Shift Del (DEL) | VAF 42/136 reads (31%) | called by mutect2, pindel, varscan2
- NRN1 | c.301del p.L101Sfs*36 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- OR10H5 | c.388del p.L130Cfs*7 | Frame Shift Del (DEL) | VAF 56/146 reads (38%) | called by mutect2, pindel, varscan2
- OSBPL1A | c.2682del p.K894Nfs*71 (on ENST00000319481 / NM_080597.4; = p.K381Nfs*71 on NM_018030.4) | Frame Shift Del (DEL) | VAF 40/73 reads (55%) | called by mutect2, varscan2
- OSBPL1A | c.1579_1580del p.S527Qfs*19 (on ENST00000319481 / NM_080597.4; = p.S14Qfs*19 on NM_018030.4) | Frame Shift Del (DEL) | VAF 38/109 reads (35%) | called by pindel, varscan2
- PARD3B | c.1241dup p.N414Kfs*70 | Frame Shift Ins (INS) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- PITPNA | c.607dup p.W203Lfs*13 | Frame Shift Ins (INS) | VAF 64/131 reads (49%) | called by mutect2, varscan2
- PLCZ1 | c.1589dup p.N530Kfs*4 | Frame Shift Ins (INS) | VAF 18/44 reads (41%) | called by mutect2, varscan2
- POLR2C | c.376del p.R126Gfs*5 | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | called by mutect2, pindel, varscan2
- PRAMEF10 | c.1086G>T p.Q362H | Missense Mutation (SNP) | VAF 117/484 reads (24%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKCSH | c.962dup p.E322Gfs*6 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | called by mutect2, varscan2*
- PSD | c.222del p.S75Hfs*37 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- PSMD1 | c.2546del p.K849Rfs*44 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | called by mutect2, pindel, varscan2
- PSPH | c.626_633dup p.Y212Pfs*9 | Frame Shift Ins (INS) | VAF 26/96 reads (27%) | called by mutect2, varscan2
- PSTPIP1 | c.837del p.A280Lfs*16 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- PTEN | c.399_403dup p.I135Kfs*2 | Frame Shift Ins (INS) | VAF 26/106 reads (25%) | called by mutect2, pindel, varscan2
- PTPRB | c.4816del p.S1606Lfs*18 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- PTPRC | c.3895dup p.S1299Kfs*41 | Frame Shift Ins (INS) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- RAD21 | c.580_587del p.E194Tfs*8 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, varscan2
- RARS1 | c.1449_1450del p.D483Efs*24 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- RDH16 | c.265_266del p.S89Rfs*23 | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | called by pindel, varscan2
- RTCB | c.736del p.M246Wfs*11 | Frame Shift Del (DEL) | VAF 30/87 reads (34%) | called by mutect2, pindel, varscan2
- RYR2 | c.10039del p.D3347Tfs*10 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | called by mutect2, pindel, varscan2
- SEC31A | c.577del p.A193Pfs*48 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, varscan2
- SESN2 | c.661del p.D221Mfs*26 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- SEZ6 | c.915del p.P306Lfs*27 | Frame Shift Del (DEL) | VAF 32/125 reads (26%) | called by mutect2, pindel, varscan2
- SIL1 | c.936del p.L313Cfs*4 | Frame Shift Del (DEL) | VAF 39/103 reads (38%) | called by mutect2, pindel, varscan2
- SLC25A52 | c.799del p.I267Sfs*9 (on ENST00000672005; = p.I257Sfs*9 on NM_001034172.4) | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | called by mutect2, pindel, varscan2
- SMAD3 | c.545del p.P182Lfs*4 | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | called by mutect2, pindel, varscan2
- SOX17 | c.1167dup p.D390Rfs*24 | Frame Shift Ins (INS) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- TBX3 | c.438del p.A147Pfs*6 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- TEX15 | c.7390del p.S2464Vfs*33 (on ENST00000256246; = p.S2847Vfs*33 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 32/83 reads (39%) | called by mutect2, pindel, varscan2
- TFPI | c.307del p.M103Cfs*11 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- THYN1 | c.581del p.N194Ifs*15 | Frame Shift Del (DEL) | VAF 30/68 reads (44%) | called by mutect2, pindel, varscan2
- TLE1 | c.730dup p.S244Kfs*3 | Frame Shift Ins (INS) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- TLN2 | c.7563dup p.L2522Tfs*10 | Frame Shift Ins (INS) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- TMEM200C | c.365del p.G122Vfs*140 | Frame Shift Del (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- TMEM41B | c.690del p.F230Lfs*6 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | called by mutect2, varscan2
- TNKS1BP1 | c.873del p.A292Qfs*43 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- TNPO3 | c.1046del p.L349Rfs*53 | Frame Shift Del (DEL) | VAF 23/63 reads (37%) | called by mutect2, pindel, varscan2
- TOP1MT | c.286del p.Y96Mfs*5 | Frame Shift Del (DEL) | VAF 51/146 reads (35%) | called by mutect2, pindel, varscan2
- TOP3A | c.128del p.N43Tfs*16 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- TRAV6 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTC31 | c.352dup p.Q118Pfs*4 | Frame Shift Ins (INS) | VAF 23/55 reads (42%) | called by mutect2, pindel, varscan2
- UGDH | c.1470_1472del p.K491del | In Frame Del (DEL) | VAF 22/53 reads (42%) | called by pindel, varscan2
- UGT1A10 | c.364del p.S122Rfs*12 | Frame Shift Del (DEL) | VAF 37/93 reads (40%) | called by mutect2, pindel, varscan2
- UNC79 | c.6543del p.F2181Lfs*10 (on ENST00000393151 / NM_001346218.2; = p.F2004Lfs*10 on NM_020818.5) | Frame Shift Del (DEL) | VAF 45/110 reads (41%) | called by mutect2, pindel, varscan2
- XRN1 | c.2012del p.L671* | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- ZNF174 | c.113del p.N38Tfs*53 | Frame Shift Del (DEL) | VAF 27/79 reads (34%) | called by mutect2, pindel, varscan2
- ZNF292 | c.452del p.L151* | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | called by mutect2, pindel, varscan2
- ZNF443 | c.622dup p.W208Lfs*9 | Frame Shift Ins (INS) | VAF 34/112 reads (30%) | called by mutect2, varscan2
- ZNF506 | c.345del p.G116Afs*5 | Frame Shift Del (DEL) | VAF 38/99 reads (38%) | called by mutect2, pindel, varscan2
- ZNF629 | c.2287dup p.L763Pfs*53 | Frame Shift Ins (INS) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- ZNF644 | c.1706del p.K569Rfs*4 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- ABCA2 | c.6654C>T p.S2218= (on ENST00000614293; = p.S2188= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as rs768971644, COSV55797707; called by muse, mutect2, varscan2
- ABCC11 | c.2304C>T p.N768= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as rs145195242; called by muse, mutect2, varscan2
- ABCC6 | c.2661C>T p.R887= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as rs376958386; called by muse, mutect2, varscan2
- ADCY4 | c.223C>T p.L75= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV99353421; called by muse, mutect2, varscan2
- AIRE | c.1254G>A p.L418= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV99381377; called by muse, mutect2, varscan2
- ALCAM | c.1536C>T p.D512= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs140620252; called by muse, mutect2, varscan2
- AMACR | c.522T>C p.T174= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100163225; called by muse, mutect2, varscan2
- ARHGAP33 | c.1113G>A p.P371= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs779915384, COSV99139772; called by muse, mutect2, varscan2
- ARID1A | c.2580C>T p.H860= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs201164050, COSV100253153; called by muse, varscan2
- ASB14 | c.1647A>G p.L549= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV99897985; called by muse, mutect2, varscan2
- ATP10B | c.489G>T p.V163= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100469705; called by muse, mutect2, varscan2
- ATP23 | c.195T>C p.Y65= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs1393319558, COSV100274519; called by muse, mutect2, varscan2
- ATP6V1H | c.1236C>T p.H412= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs142308855; called by muse, mutect2, varscan2
- ATXN2 | c.3207A>G p.V1069= (on ENST00000550104; = p.V909= on NM_002973.4) | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV101112898; called by muse, mutect2, varscan2
- BCL6B | c.1164G>A p.T388= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs749339162, COSV99546861; called by muse, mutect2, varscan2
- BCORL1 | c.3261G>A p.G1087= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV99500707; called by muse, mutect2, varscan2
- BMP5 | c.45C>G p.L15= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV63704494; called by muse, mutect2, varscan2
- BRSK1 | c.738C>T p.G246= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV58669114; called by muse, mutect2, varscan2
- C1QTNF7 | c.204C>T p.G68= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV99764935; called by muse, mutect2, varscan2
- CCNT1 | c.2127G>A p.R709= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV99980881; called by muse, mutect2, varscan2
- CDC6 | c.18C>A p.S6= | Silent (SNP) | VAF 53/110 reads (48%) | catalogued as rs143031736; called by muse, mutect2, varscan2
- CEP104 | c.414C>T p.N138= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100986366; called by muse, mutect2, varscan2
- CFAP74 | c.1209C>T p.C403= | Silent (SNP) | VAF 82/201 reads (41%) | catalogued as COSV54575018; called by muse, mutect2, varscan2
- COL22A1 | c.3408C>T p.V1136= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100280492; called by muse, mutect2, varscan2
- COL4A4 | c.1749A>G p.P583= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100307569; called by muse, mutect2, varscan2
- COL4A5 | c.4650A>G p.Q1550= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs767410335, COSV100089512; called by muse, mutect2, varscan2
- CPED1 | c.2601T>C p.N867= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as COSV100121407; called by muse, mutect2, varscan2
- CUEDC1 | c.189C>T p.Y63= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as rs764771940, COSV64226778; called by muse, mutect2, varscan2
- CYFIP2 | c.924C>T p.F308= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs539257822, COSV59029656; called by muse, mutect2, varscan2
- DCHS1 | c.7209G>A p.R2403= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV100202508; called by muse, mutect2, varscan2
- DDX42 | c.636A>G p.P212= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100835043; called by muse, mutect2, varscan2
- DHX58 | c.993C>T p.F331= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as COSV99288458; called by muse, mutect2, varscan2
- DNAH2 | c.7494C>A p.P2498= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV101209558; called by muse, mutect2, varscan2
- DRD3 | c.147G>A p.L49= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99879661; called by muse, mutect2, varscan2
- DSG3 | c.1833G>A p.P611= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs774111652, COSV57127010; called by muse, mutect2, varscan2
- E2F4 | c.828T>C p.T276= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV100681880; called by muse, mutect2, varscan2
- EIF3B | c.1335G>A p.T445= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs1168067071, COSV100703836; called by muse, mutect2, varscan2
- EIF3E | c.813G>A p.R271= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs936856066, COSV55202368; called by muse, mutect2, varscan2
- EIF3K | c.255C>T p.C85= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV99943170; called by muse, mutect2, varscan2
- EIF4G3 | c.3999C>T p.I1333= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV99945393; called by muse, mutect2, varscan2
- ELAC2 | c.2148C>T p.N716= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs759078534, COSV99309912; called by muse, mutect2, varscan2
- ENC1 | c.963T>C p.I321= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV100188225; called by muse, mutect2, varscan2
- EPAS1 | c.69G>A p.A23= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs1219457249, COSV55387013; called by muse, mutect2, varscan2
- EPPK1 | c.3813G>A p.L1271= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV101599944; called by muse, mutect2
- EXD3 | c.426C>T p.H142= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs371685558; called by muse, mutect2, varscan2
- EXOC3 | c.855C>T p.Y285= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs376240114; called by muse, mutect2, varscan2
- FADS3 | c.786G>A p.Q262= | Silent (SNP) | VAF 60/156 reads (38%) | catalogued as COSV99605474; called by muse, mutect2, varscan2
- FAM122C | c.252A>G p.E84= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100888290; called by muse, mutect2
- FBXW5 | c.1317C>T p.I439= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs934354953, COSV99812652; called by muse, mutect2, varscan2
- FCGBP | c.444C>A p.P148= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs776162506; called by muse, mutect2, varscan2
- FCRL6 | c.708G>A p.P236= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs372785343, COSV58942253; called by muse, mutect2, varscan2
- FRMD8 | c.705C>T p.R235= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100454843; called by muse, mutect2, varscan2
- FZD10 | c.1554C>T p.S518= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV57473866; called by muse, mutect2, varscan2
- GAA | c.630C>T p.S210= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs775568949, COSV100163486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAS2L3 | c.1917G>A p.Q639= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99903074; called by muse, mutect2, varscan2
- GATA1 | c.354C>A p.P118= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as COSV100936863; called by muse, mutect2, varscan2
- GHITM | c.843C>T p.Y281= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs371326384; called by muse, mutect2, varscan2
- GOLGA3 | c.6C>T p.D2= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs538287501, COSV99212520; called by muse, mutect2, varscan2
- GPR173 | c.417A>G p.T139= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100212404; called by muse, mutect2, varscan2
- GRAMD4 | c.1149C>T p.R383= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs192534639, COSV63031822; called by muse, mutect2, varscan2
- GRIN2D | c.1003C>T p.L335= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs769489288, COSV99616887; called by muse, mutect2, varscan2
- HDAC10 | c.729G>A p.L243= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV99299640; called by muse, mutect2, varscan2
- HERC2 | c.7002C>A p.S2334= | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as COSV99876408; called by muse, mutect2, varscan2
- HMGCS2 | c.81C>T p.R27= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV101024904; called by muse, mutect2, varscan2
- HNRNPF | c.267C>T p.H89= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs1484065441, COSV100563255; called by muse, mutect2, varscan2
- HRC | c.603G>A p.E201= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs571697189; called by mutect2, varscan2
- HSPG2 | c.7995G>A p.K2665= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV101021144, COSV65971520; called by muse, mutect2, varscan2
- HYAL2 | c.990C>T p.D330= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs782469848, COSV100753951; called by muse, mutect2, varscan2
- ILF3 | c.2385C>T p.G795= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs758956770, COSV51561497; called by muse, mutect2, varscan2
- INTS1 | c.1023G>A p.Q341= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs781348957, COSV101248268; called by muse, mutect2, varscan2
- INTS3 | c.1611C>T p.D537= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs765513915, COSV59678032; called by muse, mutect2, varscan2
- ITGB4 | c.2865C>T p.D955= | Silent (SNP) | VAF 56/113 reads (50%) | catalogued as rs780448706, COSV52323876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITIH5 | c.204G>A p.T68= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs143296439; called by muse, mutect2, varscan2
- ITPK1 | c.711G>A p.K237= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV99968887; called by muse, mutect2, varscan2
- ITPR3 | c.2337C>T p.H779= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as rs1183175514, COSV100968029; called by muse, mutect2, varscan2
- KANK1 | c.2169T>C p.R723= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100620067; called by muse, mutect2, varscan2
- KCNA3 | c.333C>T p.S111= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs1473851885, COSV63901715; called by muse, mutect2, varscan2
- KCNF1 | c.1110C>T p.T370= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as rs745758930, COSV99705858; called by muse, mutect2, varscan2
- KCNK1 | c.969C>G p.A323= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100785763; called by muse, mutect2, varscan2
- KIF5C | c.108T>C p.D36= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs749142685, COSV101371342; called by muse, mutect2, varscan2
- KPNA6 | c.543G>A p.E181= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV101012611; called by muse, mutect2, varscan2
- KRTAP9-4 | c.15C>T p.C5= | Silent (SNP) | VAF 72/184 reads (39%) | catalogued as rs1401579753, COSV100484946; called by muse, varscan2
- LDB3 | c.468C>T p.A156= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as rs374233873; ClinVar: likely benign; called by muse, mutect2, varscan2
- LGMN | c.1203G>A p.A401= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as rs773731547, COSV58402823; called by muse, mutect2, varscan2
- LRPAP1 | c.892C>T p.L298= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99579107; called by muse, mutect2, varscan2
- LRTM2 | c.939T>C p.I313= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV99766394; called by muse, mutect2, varscan2
- LYNX1 | c.264C>T p.Y88= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs373045729; called by muse, mutect2, varscan2
- MAP3K6 | c.1470G>A p.T490= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs749756960, COSV62887127; called by muse, varscan2
- MAT1A | c.201G>A p.L67= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs772736500, COSV100944488; called by muse, varscan2
- MLLT1 | c.336G>A p.P112= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs1394173711, COSV99398227; called by muse, mutect2, varscan2
- MSL2 | c.321C>T p.C107= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as rs1393391390, COSV99388040; called by muse, mutect2, varscan2
- MTBP | c.1302T>C p.H434= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs760166611, COSV100012515; called by muse, mutect2, varscan2
- MYLK | c.4674G>A p.T1558= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs775672251, COSV100659482; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO16 | c.2832T>C p.H944= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99194499; called by muse, mutect2, varscan2
- MYO19 | c.2332C>A p.R778= (on ENST00000614623 / NM_001163735.1; = p.R578= on NM_025109.5) | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs371727673; called by muse, mutect2, varscan2
- MYOM1 | c.105C>T p.R35= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV99868108; called by muse, mutect2
- NAE1 | c.168G>A p.S56= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs377673251; called by muse, mutect2, varscan2
- NCCRP1 | c.414C>T p.G138= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs77910816, COSV100355880; called by muse, mutect2
- NEDD9 | c.942C>T p.N314= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as rs146985170; called by muse, mutect2, varscan2
- NFATC2 | c.1881G>A p.T627= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs376812645, COSV101043558; called by muse, mutect2, varscan2
- NKX3-1 | c.333C>T p.G111= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs1230915052, COSV66512415; called by muse, mutect2, varscan2
- NOS1 | c.4143C>T p.D1381= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs750230730, COSV100500123; called by muse, mutect2, varscan2
- NOTCH1 | c.7605C>T p.G2535= | Silent (SNP) | VAF 58/122 reads (48%) | catalogued as rs757253280, COSV99491296; called by muse, mutect2, varscan2
- NR1D1 | c.180C>A p.L60= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as COSV99225765; called by muse, mutect2, varscan2
- OLFML2B | c.219G>A p.S73= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs761804582, COSV99668322, COSV99668840; called by muse, mutect2, varscan2
- OR9G4 | c.414C>T p.T138= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs149257582; called by muse, mutect2, varscan2
- OTUD7A | c.1188G>T p.T396= (on ENST00000307050 / NM_001382637.1; = p.T389= on NM_130901.3) | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs748801656, COSV100193161; called by muse, mutect2, varscan2
- PAPOLB | c.696C>A p.A232= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV101271605; called by muse, mutect2, varscan2
- PCDHA3 | c.2175G>A p.A725= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV63540850, COSV63544256; called by muse, mutect2, varscan2
- PCDHA9 | c.993T>C p.A331= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV100970023; called by muse, mutect2, varscan2
- PCDHGA3 | c.2088G>A p.A696= | Silent (SNP) | VAF 65/165 reads (39%) | catalogued as rs1379856364, COSV53975258; called by muse, mutect2, varscan2
- PDLIM4 | c.580C>T p.L194= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs761815587, COSV99517005; called by muse, mutect2, varscan2
- PDZD2 | c.8271G>A p.S2757= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs369374809; called by muse, mutect2, varscan2
- PIF1 | c.1356T>C p.A452= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV51422179; called by muse, mutect2, varscan2
- PIP5K1C | c.732C>T p.R244= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs190312515, COSV58950416; called by muse, mutect2, varscan2
- PKD1 | c.3747C>T p.D1249= | Silent (SNP) | VAF 76/175 reads (43%) | catalogued as rs148021876; called by muse, mutect2, varscan2
- PKDREJ | c.2080C>T p.L694= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99479460; called by muse, mutect2, varscan2
- PLXNB2 | c.2718G>A p.P906= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs551086650, COSV100834269; called by muse, mutect2, varscan2
- POLA2 | c.33G>A p.E11= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs1256012426, COSV99641288; called by muse, mutect2, varscan2
- PRRC2B | c.6138C>T p.S2046= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs371558194; called by muse, mutect2, varscan2
- PRSS8 | c.504C>T p.C168= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV99571759; called by muse, mutect2, varscan2
- PTPA | c.546G>A p.T182= (on ENST00000337738 / NM_178001.2; = p.T147= on NM_021131.5) | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs746005579, COSV100534177; called by muse, mutect2, varscan2
- PTPRB | c.1860C>T p.S620= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs374912045, COSV99718282; called by muse, mutect2, varscan2
- PXDN | c.3543G>A p.A1181= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as rs372544508; called by muse, mutect2, varscan2
- RNF182 | c.603C>T p.I201= | Silent (SNP) | VAF 74/187 reads (40%) | catalogued as COSV101337955; called by muse, mutect2, varscan2
- RPN1 | c.495C>A p.P165= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV99957240; called by muse, mutect2, varscan2
- SATB1 | c.1803G>A p.Q601= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as rs766256434, COSV100113105; called by muse, mutect2, varscan2
- SCN2A | c.4383A>G p.S1461= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99333174; called by muse, mutect2, varscan2
- SDK1 | c.3030A>G p.E1010= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as COSV101269771; called by muse, mutect2, varscan2
- SIGLEC1 | c.4632T>C p.P1544= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99170453; called by muse, mutect2, varscan2
- SIX3 | c.405C>T p.R135= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV99578323; called by muse, mutect2, varscan2
- SLC22A14 | c.1608C>A p.T536= | Silent (SNP) | VAF 63/136 reads (46%) | catalogued as COSV99828337; called by muse, mutect2, varscan2
- SLC47A2 | c.1056G>A p.V352= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100328228; called by muse, mutect2, varscan2
- SLCO2B1 | c.1320G>T p.V440= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV99215125; called by muse, mutect2, varscan2
- SLCO6A1 | c.276C>G p.G92= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV101134898, COSV65806331; called by muse, mutect2, varscan2
- SMURF1 | c.2142G>A p.A714= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs765505807, COSV100705487; called by muse, mutect2, varscan2
- SPPL2A | c.294T>C p.L98= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99961512; called by muse, mutect2, varscan2
- STK32C | c.768C>T p.Y256= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV100063337, COSV53838168; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2529T>C p.I843= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV100562225; called by muse, mutect2, varscan2
- STRA8 | c.528C>T p.I176= (on ENST00000275764; = p.I154= on NM_182489.2) | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1208086667, COSV51960766; called by muse, mutect2, varscan2
- SYNGAP1 | c.1572C>T p.C524= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs763080466, COSV99538923; called by muse, mutect2, varscan2
- SYVN1 | c.1437G>A p.A479= (on ENST00000377190 / NM_172230.3; = p.A478= on NM_032431.3) | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs1429318060, COSV99589145; called by muse, mutect2, varscan2
- TCN1 | c.1143A>G p.S381= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV57254121, COSV99953428; called by muse, mutect2, varscan2
- TECTA | c.177C>T p.G59= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as COSV99881311; called by muse, mutect2, varscan2
- TG | c.1048C>A p.R350= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs757630170, COSV99602867, COSV99603839; called by muse, mutect2, varscan2
- TIAM1 | c.3552G>A p.S1184= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs745941324, COSV99738392; called by muse, mutect2, varscan2
- TMEM174 | c.93C>T p.S31= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as rs140016650; called by muse, mutect2, varscan2
- TMPRSS9 | c.627C>T p.D209= (on ENST00000648592; = p.D175= on NM_182973.2) | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs781543845, COSV100211221, COSV100211683; called by muse, mutect2, varscan2
- TNK1 | c.1557C>T p.S519= (on ENST00000576812 / NM_001251902.2; = p.S514= on NM_003985.5) | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV100247994; called by muse, mutect2, varscan2
- TNRC6C | c.1428A>G p.T476= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs1279352953, COSV100050584; called by muse, mutect2, varscan2
37 further variants in this file (0 protein-altering or splice-affecting, 17 silent, 20 other) are not listed here.
